Somatic mutation profile of tumor specimen MP2PRT-PAVPBN-TBP1-A (aliquot MP2PRT-PAVPBN-TBP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVPBN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,972 days).
Specimen MP2PRT-PAVPBN-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74f25dac-f10d-4707-a966-f0282f09e657.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPBN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPBN-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a4574d0-4baf-48e0-aa49-d4a6ca5ac367

The open-access MAF lists 21 somatic variants for this specimen: 11 protein-altering or splice-affecting, 10 silent.
By variant classification: Silent 10, Missense Mutation 9, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL5 | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59935633; called by muse, mutect2, varscan2
- CHRM1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 141/553 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs1382129041, COSV61007475; called by muse, mutect2, varscan2
- NSD2 | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 74/735 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.368); catalogued as rs1271075487; called by muse, mutect2, varscan2
- RYR2 | c.7315G>A p.A2439T | Missense Mutation (SNP) | VAF 65/290 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs367818536, CM1414692; called by muse, mutect2, varscan2
- XPR1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as rs1177628270; called by muse, mutect2, varscan2
- ZSCAN1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 179/682 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs771662377, COSV56603907; called by muse, mutect2, varscan2
- ALG3 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 113/334 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- DAAM1 | c.2008G>C p.D670H | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IGHV3-66 | chr14:106675009 ACTGTGTCTCTCGCACAGTAA>GCTT | Missense Mutation (DEL) | VAF 59/189 reads (31%) | called by pindel, varscan2*
- IGLV4-69 | c.358dup p.*120P | In Frame Ins (INS) | VAF 47/193 reads (24%) | called by mutect2, varscan2
- LRRC8C | c.1640_1644delinsCCGCCCC p.L547Pfs*35 | Frame Shift Ins (INS) | VAF 89/363 reads (25%) | called by muse*, pindel
- CAMTA1 | c.5021G>A p.*1674= | Silent (SNP) | VAF 47/406 reads (12%) | called by muse, mutect2, varscan2
- FAM193A | c.2586A>G p.P862= | Silent (SNP) | VAF 104/502 reads (21%) | called by muse, mutect2, varscan2
- IGHV3-53 | c.349_350insGTCCCGG p.*117delinsGPG | Silent (INS) | VAF 28/194 reads (14%) | called by pindel, varscan2
- IGLV4-69 | c.359delinsCC p.*120P | Silent (INS) | VAF 61/271 reads (23%) | called by mutect2*, pindel, varscan2*
- OR7C2 | c.552C>T p.V184= | Silent (SNP) | VAF 90/312 reads (29%) | called by muse, mutect2, varscan2
- PADI6 | c.1047C>T p.D349= | Silent (SNP) | VAF 96/396 reads (24%) | catalogued as COSV61885211; called by muse, mutect2, varscan2
- PDGFC | c.198T>A p.T66= | Silent (SNP) | VAF 126/472 reads (27%) | catalogued as COSV56850005; called by muse, mutect2, varscan2
- SLC12A4 | c.2220C>T p.G740= | Silent (SNP) | VAF 82/337 reads (24%) | catalogued as rs567542501; called by muse, mutect2, varscan2
- SLC28A3 | c.306G>T p.R102= | Silent (SNP) | VAF 45/288 reads (16%) | called by muse, mutect2, varscan2
- SLITRK6 | c.141T>C p.N47= | Silent (SNP) | VAF 102/400 reads (26%) | called by muse, mutect2, varscan2
